Somatic mutation profile of tumor specimen TCGA-D8-A1JH-01A (aliquot TCGA-D8-A1JH-01A-11D-A188-09) from TCGA case TCGA-D8-A1JH, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 56.1 years (20,497 days).
Specimen TCGA-D8-A1JH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 801b9cb3-2fc2-449a-a10d-496b95085c40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1JH-10A (Blood Derived Normal), aliquot TCGA-D8-A1JH-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/680c7118-8850-424a-b7a2-081cd37e7d5a

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Intron 2, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 20/68 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCT6B | c.356T>C p.I119T | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); catalogued as rs1039799613, COSV58488375, COSV58488539; called by muse, mutect2, varscan2
- CD99 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 113/493 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.397); catalogued as rs1185087023, COSV66989310; called by muse, mutect2, varscan2
- CPT2 | c.623A>G p.N208S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1274903903, COSV53758996; called by muse, mutect2, varscan2
- DCAF6 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100393820, COSV56576961; called by muse, mutect2, varscan2
- DGKB | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs747038198, COSV51762576; called by muse, mutect2, varscan2
- IRGC | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs528054051, COSV54983505; called by muse, mutect2, varscan2
- LYN | c.327del p.E110Kfs*15 | Frame Shift Del (DEL) | VAF 28/158 reads (18%) | catalogued as rs1266824391, COSV99066642; called by mutect2, pindel, varscan2
- MAP3K1 | c.4310G>C p.C1437S | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68122771, COSV68126501; called by muse, mutect2, varscan2
- MED23 | c.1718A>G p.Y573C | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); catalogued as COSV63430340; called by muse, mutect2, varscan2
- RBM39 | c.452A>T p.D151V | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53614590, COSV53614751; called by muse, mutect2, varscan2
- SUPT16H | c.905A>G p.Y302C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV53523355; called by muse, mutect2, varscan2
- UGT1A1 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs1247729976, COSV59389360; called by muse, mutect2
- GTF2I | c.2795C>G p.S932C (on ENST00000573035 / NM_032999.4; = p.S891C on NM_001518.5) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- KDM6A | c.1548dup p.Q517Tfs*9 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | called by mutect2, pindel
- MAP3K1 | c.3646_3649dup p.I1217Nfs*23 | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | called by mutect2, pindel
- AKAP4 | c.435C>T p.G145= | Silent (SNP) | VAF 39/155 reads (25%) | catalogued as COSV100654263, COSV62074043; called by muse, mutect2, varscan2
- ATF4 | c.286T>C p.L96= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV57478082; called by muse, mutect2, varscan2
- RASD2 | c.243C>T p.P81= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs751120892, COSV53352231; called by muse, mutect2, varscan2
- SFTPA1 | c.351A>G p.Q117= | Silent (SNP) | VAF 8/158 reads (5%) | catalogued as COSV100957057; called by muse, mutect2
- CASP8 | c.1-8144G>T | Intron (SNP) | VAF 28/126 reads (22%) | catalogued as COSV51848394, COSV51852613; called by muse, mutect2, varscan2
- SLC35A2 | c.1163+46G>T | Intron (SNP) | VAF 15/64 reads (23%) | catalogued as COSV99504384; called by muse, mutect2, varscan2
